MMRF case MMRF_2122 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f7542c01-7526-482f-b427-a1beabea6af2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.0 years (24,480 days); ISS stage: II; Days to last known disease status: 895 days (2.5 years); Days to last follow up: 895 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 602 days (1.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 609 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 615 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.761 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.13 mg/dL; Immunoglobulin G 2.38 g/L; Immunoglobulin A 80.4 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.83 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.78 mmol/L; Albumin 25 g/L; Total Protein 10.9 g/dL; Glucose 7.21 mmol/L.
- Day 104 (ECOG 1): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 5.09 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.58 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 12.2 mmol/L.
- Day 194 (ECOG 0): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 6.48 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 14.6 mmol/L.
- Day 257 (ECOG 0): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.66 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 10.2 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 15.1 mmol/L.
- Day 349 (ECOG 0): M Protein 1.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.64 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 18.3 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 13.9 mmol/L.
- Day 432 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.65 mg/dL; Immunoglobulin G 9.62 g/L; Immunoglobulin A 29 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.42 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 8.6 g/dL; Glucose 16 mmol/L.
- Day 524 (ECOG 0): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.17 mg/dL; Immunoglobulin G 8.09 g/L; Immunoglobulin A 44.5 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.53 mmol/L; Albumin 34 g/L; Total Protein 9.7 g/dL; Glucose 16.3 mmol/L.
- Day 621 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.56 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 24.2 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.38 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 8.1 g/dL; Glucose 16.1 mmol/L.
- Day 729 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.18 mg/dL; Immunoglobulin G 9.59 g/L; Immunoglobulin A 12.6 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.09 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 12 mmol/L.
- Day 811 (ECOG 1): M Protein 0.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 9.75 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.97 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 12.2 mmol/L.
- Day 895 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 7.6 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 13.6 mmol/L.

Other clinical attributes
- Day -6: Weight: 178 kg; Height: 166 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2122_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2122_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
- Sample MMRF_2122_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 524 days (1.4 years).
